Somatic mutation profile of tumor specimen TCGA-F7-7848-01A (aliquot TCGA-F7-7848-01A-11D-2129-08) from TCGA case TCGA-F7-7848, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.2 years (17,251 days).
Specimen TCGA-F7-7848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24a1d832-01d4-4978-a9e1-3bcd070f1a49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-7848-10A (Blood Derived Normal), aliquot TCGA-F7-7848-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65396110-e4b0-4c96-9256-ba23fea700c4

The open-access MAF lists 351 somatic variants for this specimen: 262 protein-altering or splice-affecting, 82 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 82, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 6, Splice Region 4, Intron 4, RNA 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNND2 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs886041494, COSV100481426; ClinVar: likely pathogenic; called by mutect2, varscan2
- PAH | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486763160, CM123243, COSV100188011; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1996T>A p.S666T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99710385; called by muse, mutect2, varscan2
- ABCC12 | c.3741G>T p.Q1247H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs1567442631, COSV60915024; called by muse, mutect2, varscan2
- ABCD3 | c.1432G>T p.G478* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100931369; called by muse, mutect2, varscan2
- ACTBL2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs749573829, COSV101379324; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV54448826; called by muse, mutect2, varscan2
- ADCY1 | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as COSV99811928; called by muse, mutect2, varscan2
- ADCY8 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV99652112; called by muse, mutect2, varscan2
- AFF3 | c.1968C>A p.S656R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100418766; called by muse, mutect2, varscan2
- AKR1D1 | c.459G>T p.A153= | Splice Region (SNP) | VAF 49/173 reads (28%) | catalogued as rs753492606, COSV54340909, COSV99653035; called by muse, mutect2, varscan2
- AL592490.1 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV101308182; called by muse, mutect2, varscan2
- ALDH18A1 | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM127892, COSV100973162; called by muse, varscan2
- ALPG | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99779304; called by muse, varscan2
- AMOTL1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 48/103 reads (47%) | catalogued as COSV100133774; called by muse, mutect2, varscan2
- ANKRD50 | c.1423A>C p.M475L | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101538950; called by muse, mutect2, varscan2
- APOB | c.5008G>T p.E1670* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99265502; called by muse, mutect2, varscan2
- ARF6 | c.314G>C p.R105P | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100028427; called by muse, mutect2, varscan2
- ATN1 | c.2779G>T p.D927Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100755781; called by muse, mutect2, varscan2
- ATP10A | c.2993G>T p.C998F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100791199; called by muse, mutect2, varscan2
- ATP2A1 | c.465G>T p.V155= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100837290; called by muse, mutect2, varscan2
- ATR | c.6596A>G p.N2199S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100638195; called by muse, mutect2, varscan2
- AUTS2 | c.3291G>C p.R1097S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV99048180; called by mutect2, varscan2
- BCAS1 | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV101006162; called by muse, mutect2
- BEST2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as rs775360080, COSV50363086; called by muse, mutect2, varscan2
- BFSP2 | c.334G>T p.G112W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100183742; called by muse, mutect2, varscan2
- BMPER | c.1315C>A p.R439S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV51830758, COSV99779557; called by muse, mutect2, varscan2
- BTC | c.339A>T p.R113S | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV101201527; called by muse, mutect2, varscan2
- CATSPERD | c.2069A>G p.Y690C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.818); catalogued as COSV100486780, COSV100486869; called by muse, mutect2, varscan2
- CCDC85A | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV101339464, COSV68154085; called by muse, mutect2, varscan2
- CCL20 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1436561042, COSV100721815; called by muse, mutect2, varscan2
- CCNB1IP1 | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100738561; called by muse, mutect2
- CDH12 | c.2116C>A p.P706T | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV101202475; called by muse, mutect2
- CDH9 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as rs1272336502, COSV99144396; called by muse, mutect2, varscan2
- CDHR2 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991540; called by muse, mutect2, varscan2
- CDON | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV99701289; called by muse, mutect2, varscan2
- CELF5 | c.993C>A p.H331Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99485934; called by muse, mutect2, varscan2
- CEP350 | c.5555G>T p.R1852L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs761924454, COSV62598953, COSV62610047; called by muse, mutect2, varscan2
- CERS2 | c.957G>C p.W319C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644543; called by muse, mutect2, varscan2
- CFH | c.2411C>A p.S804* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100809499; called by muse, mutect2, varscan2
- CHAT | c.2091C>A p.H697Q | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV100340111; called by muse, mutect2, varscan2
- CHL1 | c.2449G>T p.G817W (on ENST00000397491 / NM_001253387.1; = p.G833W on NM_006614.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99851111; called by muse, mutect2, varscan2
- CKAP2 | c.793C>T p.R265W (on ENST00000378037 / NM_001098525.2; = p.R264W on NM_018204.5) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs545281527, COSV51622861; called by muse, mutect2, varscan2
- CLEC4D | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100222989; called by muse, mutect2
- CNTN3 | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99724289; called by muse, mutect2
- COL10A1 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866996811, COSV99684227; called by muse, mutect2, varscan2
- COL11A1 | c.4559C>A p.P1520H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100616415, COSV100618580, COSV62182916; called by muse, mutect2, varscan2
- COL24A1 | c.4586A>G p.H1529R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100993255; called by muse, mutect2, varscan2
- COL4A3 | c.4235G>A p.G1412D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034407, CM161092, COSV101170276, COSV67412722; called by muse, mutect2, varscan2
- CPT1A | c.1410C>A p.N470K | Missense Mutation (SNP) | VAF 105/161 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99681120; called by muse, mutect2, varscan2
- CSMD3 | c.10310C>T p.T3437I (on ENST00000297405 / NM_001363185.1; = p.T3268I on NM_052900.3) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52225702, COSV99833409; called by muse, mutect2, varscan2
- CSMD3 | c.7952G>C p.G2651A (on ENST00000297405 / NM_001363185.1; = p.G2547A on NM_052900.3) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99833414; called by muse, mutect2, varscan2
- CSMD3 | c.4192G>T p.G1398W (on ENST00000297405 / NM_001363185.1; = p.G1294W on NM_052900.3) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52241135; called by muse, mutect2, varscan2
- CXorf21 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.93); PolyPhen benign (0.033); catalogued as COSV100973276; called by muse, mutect2, varscan2
- DAB1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160502425, COSV100139985, COSV59729336; called by muse, mutect2, varscan2
- DDX20 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100865925; called by muse, mutect2, varscan2
- DENND4B | c.1040G>C p.R347P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.581); catalogued as COSV100768627; called by muse, mutect2, varscan2
- DGKI | c.830A>G p.H277R | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as rs1228749751, COSV99934192; called by muse, mutect2, varscan2
- DLK1 | c.76T>G p.C26G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100375205; called by muse, mutect2, varscan2
- DMD | c.8740G>C p.E2914Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1556656366, CM150622, COSV100627161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100819032; called by muse, mutect2, varscan2
- DMRTC2 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99523384; called by muse, mutect2, varscan2
- DNAH11 | c.1773T>A p.H591Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV100179153; called by muse, mutect2, varscan2
- DZIP1 | c.2470G>A p.A824T (on ENST00000347108; = p.A805T on NM_014934.5) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100714083; called by muse, mutect2, varscan2
- ELMO1 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV100164366, COSV60302254, COSV99068342; called by muse, mutect2, varscan2
- EPC2 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV51551610, COSV99309537; called by muse, mutect2, varscan2
- EXOC1 | c.2081G>T p.R694L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV100637855; called by muse, mutect2, varscan2
- EYS | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.637); catalogued as COSV100676395; called by muse, mutect2, varscan2
- FBN2 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV99327241; called by muse, mutect2, varscan2
- FGA | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.047); catalogued as COSV100120370; called by muse, mutect2, varscan2
- FLG | c.8149C>T p.Q2717* | Nonsense Mutation (SNP) | VAF 24/358 reads (7%) | catalogued as rs1409980117; called by muse, mutect2, varscan2
- FRMPD2 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100563809; called by muse, mutect2, varscan2
- FSIP2 | c.18674C>A p.S6225Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100555053, COSV58101976; called by muse, mutect2, varscan2
- FSTL5 | c.1726del p.L576Wfs*38 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV100061328; called by mutect2, pindel, varscan2
- FSTL5 | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100055068; called by muse, mutect2, varscan2
- FUT6 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs364637; called by muse, mutect2
- GABRA2 | c.1270G>C p.V424L | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100734212, COSV62912898; called by muse, mutect2, varscan2
- GBGT1 | c.730A>T p.R244W | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100923771; called by muse, mutect2, varscan2
- GK2 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100725943, COSV104415790; called by muse, mutect2, varscan2
- GRAMD4 | c.822A>G p.I274M | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100730463; called by muse, mutect2, varscan2
- GRIN2A | c.3585C>A p.D1195E | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100409674; called by muse, mutect2, varscan2
- GRIN2B | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as COSV101663022; called by muse, mutect2, varscan2
- GRM1 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs543060388, COSV99266029; called by muse, mutect2, varscan2
- H1-6 | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100619530; called by muse, mutect2, varscan2
- HECTD2 | c.497A>T p.N166I | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV99978534; called by muse, mutect2, varscan2
- HECW2 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV99647057; called by muse, mutect2, varscan2
- HMCN1 | c.9887G>T p.R3296L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV99628838; called by muse, mutect2, varscan2
- HMCN1 | c.12689T>C p.V4230A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as COSV99628842; called by muse, mutect2, varscan2
- HOXD10 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV99982730; called by muse, mutect2, varscan2
- HPS4 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100404318; called by muse, mutect2, varscan2
- HTT | c.4642G>A p.D1548N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770827394, COSV61861503; called by muse, mutect2, varscan2
- IFT140 | c.3506A>G p.E1169G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100794306; called by muse, mutect2, varscan2
- IL12RB2 | c.2110C>A p.P704T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99255033; called by muse, mutect2, varscan2
- IL12RB2 | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV52025270, COSV99255037; called by muse, mutect2, varscan2
- IMPA1 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777151679, COSV99808930; called by muse, mutect2, varscan2
- IMPG2 | c.1652C>G p.S551C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99515503; called by muse, mutect2, varscan2
- IQCB1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138646990, COSV100181733; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1233G>C p.Q411H (on ENST00000485419 / NM_001197113.1; = p.Q335H on NM_014575.3) | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768556152, COSV100540813; called by muse, mutect2, varscan2
- IQUB | c.1741G>T p.V581F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100227068; called by muse, mutect2, varscan2
- ITIH6 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99513257; called by muse, mutect2, varscan2
- IVL | c.1682C>G p.T561R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.177); catalogued as COSV100908155; called by muse, mutect2, varscan2
- KCND2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752601891, COSV58600481; called by muse, mutect2, varscan2
- KCNMA1 | c.3266C>T p.P1089L (on ENST00000286628 / NM_001161352.2; = p.P1031L on NM_002247.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.326); catalogued as rs1208962527, COSV99694646, COSV99697151; called by muse, mutect2, varscan2
- KCNMA1 | c.1421A>G p.H474R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.366); catalogued as COSV99697164; called by muse, mutect2, varscan2
- KDM2B | c.3247T>A p.C1083S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100997396; called by muse, mutect2, varscan2
- KHDRBS2 | c.893+1G>T p.X298_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99833395; called by mutect2, varscan2
- KIF13B | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV101580666; called by muse, mutect2
- KIF20B | c.5241A>T p.K1747N (on ENST00000371728 / NM_001284259.2; = p.K1707N on NM_016195.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99589955; called by muse, mutect2
- KIRREL2 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); catalogued as COSV99383959; called by muse, mutect2, varscan2
- KLF8 | c.959A>T p.E320V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100808233; called by muse, mutect2, varscan2
- KLHL32 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs759230880, COSV100987268; called by muse, mutect2, varscan2
- KLKB1 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99249923; called by muse, mutect2, varscan2
- LAMA2 | c.3067T>A p.C1023S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370431; called by muse, mutect2, varscan2
- LIN7A | c.89C>G p.A30G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99692075; called by muse, mutect2, varscan2
- LRP2 | c.13008G>T p.Q4336H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV99788288; called by muse, mutect2, varscan2
- LTA | c.35T>G p.V12G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101403184; called by muse, mutect2, varscan2
- LTF | c.1909-1G>T p.X637_splice | Splice Site (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99208089; called by muse, mutect2, varscan2
- LTK | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs887249080, COSV99778929; called by muse, mutect2, varscan2
- MAP2 | c.2441del p.G814Afs*9 | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | catalogued as COSV52288369; called by mutect2, pindel, varscan2
- MED12 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1482172384, COSV100377867, COSV100379778, COSV61345467; called by muse, mutect2, varscan2
- MED12 | c.4580A>G p.Q1527R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100377869; called by muse, mutect2, varscan2
- MINDY3 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1447412638, COSV99510452, COSV99510725; called by muse, mutect2, varscan2
- MME | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.428); catalogued as COSV100852383; called by muse, mutect2, varscan2
- MMP8 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99368427; called by muse, mutect2, varscan2
- MOCS1 | c.1666C>T p.H556Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV99225614; called by muse, mutect2, varscan2
- MORF4L2 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as COSV100846365; called by muse, mutect2, varscan2
- MPHOSPH6 | c.384G>C p.K128N | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99259200; called by muse, mutect2, varscan2
- MRGPRX4 | c.548G>C p.W183S | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100049718; called by muse, mutect2, varscan2
- MROH1 | c.4194G>A p.V1398= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as rs1393622819; called by muse, mutect2, varscan2
- MROH2B | c.2562C>A p.D854E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV101270664; called by muse, mutect2, varscan2
- MS4A14 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV55734556; called by muse, mutect2, varscan2
- MST1R | c.2895G>T p.L965F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as COSV99618609; called by muse, mutect2
- MTMR7 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99472367; called by muse, mutect2, varscan2
- MTREX | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100043992; called by muse, mutect2, varscan2
- MUSK | c.1971C>A p.Y657* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as COSV51897072; called by muse, mutect2, varscan2
- MYBBP1A | c.3683C>G p.P1228R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV99625989; called by muse, mutect2, varscan2
- MYH2 | c.3631G>T p.E1211* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV99820060; called by muse, mutect2, varscan2
- NACC1 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99456960; called by muse, mutect2
- NAT1 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100306515; called by muse, mutect2, varscan2
- NBEA | c.1225G>C p.G409R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100079869; called by muse, mutect2, varscan2
- NFE2L3 | c.1880G>T p.C627F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99283686; called by muse, mutect2, varscan2
- NLRP12 | c.2699G>T p.G900V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100144865, COSV100146050; called by muse, mutect2, varscan2
- NLRP7 | c.2323C>A p.P775T (on ENST00000340844 / NM_206828.3; = p.P747T on NM_139176.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555863660, COSV100052257; called by muse, mutect2, varscan2
- NLRP8 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV99405232; called by muse, mutect2, varscan2
- NRK | c.3139G>T p.A1047S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs368671831, COSV99687657; called by muse, mutect2, varscan2
- NRXN3 | c.769C>A p.L257M (on ENST00000557594 / NM_001272020.2; = p.L889M on NM_004796.6) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99818541; called by muse, mutect2, varscan2
- NSD2 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100373239; called by muse, mutect2, varscan2
- NSD2 | c.3898C>A p.P1300T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100373240; called by muse, mutect2, varscan2
- OLFM3 | c.496G>T p.D166Y (on ENST00000338858 / NM_001288821.1; = p.D146Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100129446; called by muse, mutect2, varscan2
- OR13G1 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100687233; called by muse, mutect2, varscan2
- OR2A4 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100199673; called by muse, mutect2, varscan2
- OR2B3 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV101013788; called by muse, mutect2, varscan2
- OR2G6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1373274698, COSV100598133; called by muse, mutect2, varscan2
- OR2T6 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs777341883, COSV100861557; called by muse, mutect2, varscan2
- OR4Q3 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV59179282; called by muse, mutect2, varscan2
- OR5H15 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100736661; called by muse, varscan2
- OR6C65 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs970262942, COSV101110188; called by muse, mutect2, varscan2
- OR8J3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs201535279; called by muse, mutect2
- OTUD7A | c.669C>G p.H223Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100192431, COSV61037805; called by muse, mutect2, varscan2
- PALB2 | c.2483G>T p.C828F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV99848483; called by muse, mutect2, varscan2
- PAPPA2 | c.3250G>T p.G1084* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100868050; called by muse, mutect2, varscan2
- PAPPA2 | c.3413G>C p.G1138A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100868052; called by muse, mutect2, varscan2
- PAPPA2 | c.3983C>G p.T1328S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100868053; called by muse, mutect2, varscan2
- PCLO | c.11234C>A p.T3745K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100432121; called by muse, mutect2, varscan2
- PDE3A | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100762084; called by muse, mutect2, varscan2
- PDZD2 | c.327C>A p.H109Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV99224882; called by muse, mutect2, varscan2
- PEG3 | c.2714A>T p.Q905L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99688821; called by muse, mutect2, varscan2
- PER3 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs550440452, COSV100728333; called by muse, mutect2, varscan2
- PKHD1 | c.6866-1G>A p.X2289_splice | Splice Site (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100582991; called by muse, mutect2, varscan2
- PLA2R1 | c.2402-1G>A p.X801_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV51778178; called by muse, mutect2, varscan2
- PLEKHG4 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58573913; called by muse, mutect2
- PLXNA1 | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs201695917, COSV99302967; called by muse, mutect2, varscan2
- PLXNA1 | c.2773G>A p.G925R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as rs1363217701, COSV52532441; called by muse, mutect2, varscan2
- POLR2A | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100495764; called by muse, mutect2, varscan2
- PROX1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV99799339; called by muse, mutect2, varscan2
- PTDSS1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894531875, COSV100428639; called by muse, mutect2, varscan2
- PTGS1 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.33); catalogued as COSV99793151; called by muse, mutect2, varscan2
- PTPRD | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1318804406, COSV100644711; called by muse, mutect2, varscan2
- QARS1 | c.1054A>C p.R352= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100069998; called by muse, mutect2
- QPCTL | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs369332200, COSV99171265; called by muse, mutect2, varscan2
- RALGAPA1 | c.3868C>T p.R1290* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99354596; called by muse, mutect2, varscan2
- RBBP6 | c.1664T>G p.V555G | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV100154577; called by muse, mutect2, varscan2
- RGS7 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100467219; called by muse, mutect2, varscan2
- RHAG | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100006574; called by muse, mutect2, varscan2
- RIMS3 | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101013399; called by muse, mutect2, varscan2
- RNF220 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100698550; called by muse, mutect2, varscan2
- ROS1 | c.6544C>T p.P2182S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.1); catalogued as rs760792633, COSV63859333; called by muse, mutect2, varscan2
- RPL10L | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV100022411; called by muse, mutect2, varscan2
- RUNX1T1 | c.1101G>T p.M367I (on ENST00000265814 / NM_001198628.1; = p.M340I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99751817; called by muse, mutect2, varscan2
- RYR2 | c.11359G>T p.V3787L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100769966; called by muse, mutect2, varscan2
- RYR3 | c.1004A>T p.K335M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101212696; called by muse, mutect2, varscan2
- SALL2 | c.2141T>G p.L714R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100444333; called by muse, mutect2, varscan2
- SBF1 | c.4616A>G p.Y1539C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100817715; called by muse, mutect2, varscan2
- SCN2A | c.5221T>A p.S1741T | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV99331535; called by muse, mutect2, varscan2
- SLA | c.422G>T p.W141L (on ENST00000338087 / NM_001045556.3; = p.W181L on NM_006748.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600707; called by muse, mutect2, varscan2
- SLC19A3 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99295824; called by muse, mutect2, varscan2
- SLC25A13 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55703513; called by muse, mutect2, varscan2
- SLC35F3 | c.427A>T p.N143Y (on ENST00000366617 / NM_001300845.1; = p.N212Y on NM_173508.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV100784778; called by muse, mutect2, varscan2
- SLC35F3 | c.530C>A p.T177N (on ENST00000366617 / NM_001300845.1; = p.T246N on NM_173508.4) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV100784779; called by muse, mutect2, varscan2
- SLC39A10 | c.1673G>A p.W558* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100660598; called by muse, mutect2, varscan2
- SLC39A8 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs757798247, COSV100765724; called by muse, mutect2, varscan2
- SLC47A1 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99565283; called by muse, mutect2, varscan2
- SLC47A1 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV99565284; called by muse, mutect2, varscan2
- SLC5A4 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV99831900; called by muse, mutect2, varscan2
- SLC8A1 | c.1260G>C p.E420D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100245209, COSV100245911; called by muse, mutect2, varscan2
- SLC9C1 | c.1441T>C p.Y481H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99997899; called by muse, mutect2, varscan2
- SLCO1B1 | c.227-1G>C p.X76_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99918422; called by muse, mutect2, varscan2
- SLITRK3 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV99579176; called by muse, mutect2, varscan2
- SLITRK5 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100280717; called by muse, mutect2, varscan2
- SOX7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1403240275, COSV100449059; called by muse, mutect2, varscan2
- SPATA5L1 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99973038; called by muse, mutect2
- SPOCK1 | c.287T>G p.V96G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99968895; called by muse, mutect2, varscan2
- SPOCK3 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100692962; called by muse, mutect2, varscan2
- SPTBN4 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs770792509, COSV58953694; called by muse, mutect2, varscan2
- SRRT | c.1846del p.L616Cfs*59 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | catalogued as COSV53818743; called by mutect2, pindel, varscan2
- SSTR1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57456694, COSV99942871; called by muse, mutect2, varscan2
- STAG3 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs767644022, COSV100425888, COSV100426065; called by muse, mutect2, varscan2
- STX4 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100572932; called by muse, mutect2
- SUGCT | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100001574; called by muse, mutect2, varscan2
- SULF1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 21/168 reads (13%) | catalogued as COSV52677297, COSV99482980; called by muse, mutect2, varscan2
- SV2B | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1419973507, COSV100370633; called by muse, mutect2
- SYNE1 | c.21173A>C p.Q7058P (on ENST00000367255 / NM_182961.4; = p.Q6987P on NM_033071.3) | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99563072; called by muse, mutect2, varscan2
- SYNE1 | c.12850G>T p.A4284S (on ENST00000367255 / NM_182961.4; = p.A4213S on NM_033071.3) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99563074; called by muse, mutect2, varscan2
- TAS2R40 | c.703A>T p.R235W | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101282994; called by muse, mutect2, varscan2
- TENM1 | c.3680G>A p.S1227N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100949942, COSV64429069; called by muse, mutect2, varscan2
- TENM3 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV101305105; called by muse, mutect2, varscan2
- TEX11 | c.697C>A p.Q233K (on ENST00000344304; = p.Q218K on NM_031276.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100721659; called by muse, mutect2
- TJP1 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100632689; called by muse, mutect2, varscan2
- TLL1 | c.201T>A p.D67E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV50262026; called by muse, mutect2
- TP53 | c.173del p.P58Qfs*65 | Frame Shift Del (DEL) | VAF 44/205 reads (21%) | catalogued as COSV52675650, COSV53041942, COSV53097051; called by mutect2, pindel, varscan2
- TRMT44 | c.2218C>T p.H740Y | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101077689; called by muse, mutect2, varscan2
- TTN | c.20382G>A p.M6794I (on ENST00000591111; = p.M5867I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | PolyPhen benign (0); catalogued as COSV100611445; called by muse, mutect2, varscan2
- UAP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as COSV99617695; called by muse, mutect2, varscan2
- UBR5 | c.1895-2A>G p.X632_splice | Splice Site (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99640772; called by muse, mutect2
- XYLT1 | c.2289G>T p.M763I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.253); catalogued as COSV99761650; called by muse, mutect2, varscan2
- YEATS2 | c.1715A>T p.K572M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100527771; called by muse, mutect2, varscan2
- YTHDC1 | c.1702C>T p.R568* (on ENST00000344157 / NM_001031732.4; = p.R550* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as rs1436159985, COSV60010246, COSV60012500; called by muse, mutect2
- YTHDC2 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs764918921, COSV99363253; called by muse, mutect2, varscan2
- ZFP64 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53798746, COSV99402427; called by muse, mutect2, varscan2
- ZIM3 | c.1403G>T p.R468I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs539722568, COSV54140735, COSV54143087; called by muse, mutect2, varscan2
- ZNF12 | c.814A>T p.S272C (on ENST00000405858 / NM_016265.4; = p.S234C on NM_006956.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV100703698; called by muse, mutect2, varscan2
- ZNF217 | c.912A>T p.K304N | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100184446; called by muse, mutect2, varscan2
- ZNF440 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100407520; called by muse, mutect2, varscan2
- ZNF530 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100252578, COSV100252772; called by muse, mutect2, varscan2
- ZNF536 | c.1216C>G p.P406A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100835189, COSV62823340; called by muse, mutect2, varscan2
- ZNF654 | c.3105A>C p.E1035D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV100525714; called by muse, mutect2, varscan2
- ZNF668 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.063); catalogued as rs1254769533, COSV100336640; called by muse, mutect2, varscan2
- ZNF700 | c.1421A>T p.Y474F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99583506; called by muse, mutect2, varscan2
- ZNF780B | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.891); catalogued as COSV99665637; called by muse, mutect2, varscan2
- ZNF804A | c.3368A>C p.K1123T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100167714; called by muse, mutect2, varscan2
- ABCA10 | c.4137del p.W1379Cfs*17 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1012_1013insC p.I338Tfs*5 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel*
- IGKV3D-11 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IGSF22 | c.534del p.K179Rfs*47 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | called by mutect2, pindel, varscan2
- KEL | c.1298dup p.S434Efs*29 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel
- LHFPL3 | c.533dup p.A179Gfs*20 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MAML2 | c.2518_2519del p.T840Hfs*36 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by pindel, varscan2
- MRC1 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NSD1 | c.3284del p.G1095Afs*3 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- TRBC2 | c.162T>G p.S54R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- ALDOB | c.1095G>A p.*365= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100878865; called by muse, mutect2, varscan2
- ANK2 | c.1330T>C p.L444= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs1297909649, COSV100001479; called by muse, mutect2, varscan2
- ART3 | c.261T>C p.P87= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs1275812976, COSV100587757; called by muse, mutect2, varscan2
- BACH2 | c.1344T>C p.Y448= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs770645890, COSV99999279; called by muse, mutect2, varscan2
- BCL6B | c.264C>G p.G88= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV99546609; called by muse, mutect2, varscan2
- BTN3A3 | c.1116A>T p.P372= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV55073152, COSV99764872; called by muse, mutect2, varscan2
- CAAP1 | c.696C>T p.S232= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs749407972, COSV61701278; called by muse, mutect2, varscan2
- CCDC138 | c.1683G>T p.T561= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99719091; called by muse, mutect2, varscan2
- CDH12 | c.2118C>A p.P706= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV101202474; called by muse, mutect2
- CDH9 | c.114G>T p.A38= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs773476075, COSV50464582; called by muse, mutect2, varscan2
- CDR1 | c.612G>A p.K204= | Silent (SNP) | VAF 81/142 reads (57%) | catalogued as COSV100983406; called by muse, mutect2, varscan2
- CEP78 | c.1665A>C p.S555= (on ENST00000424347 / NM_001349840.2; = p.S556= on NM_032171.3) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99450394; called by muse, mutect2, varscan2
- CFAP47 | c.2259T>G p.P753= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV99934969; called by muse, mutect2, varscan2
- CFAP61 | c.1704G>A p.R568= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99844703; called by muse, mutect2, varscan2
- CFH | c.2886T>A p.G962= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100809500; called by muse, mutect2, varscan2
- CFTR | c.3195T>A p.L1065= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99135938; called by muse, mutect2, varscan2
- CHD7 | c.6291C>T p.D2097= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1414492044, COSV101418237; called by muse, mutect2, varscan2
- COL11A1 | c.4560C>A p.P1520= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100616414; called by muse, mutect2, varscan2
- CUBN | c.5454C>T p.L1818= | Silent (SNP) | VAF 108/279 reads (39%) | catalogued as COSV100912195, COSV100912629; called by muse, mutect2, varscan2
- CYTIP | c.826C>A p.R276= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99938588, COSV99938736; called by muse, mutect2, varscan2
- DICER1 | c.2398A>C p.R800= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV100602064; called by muse, mutect2, varscan2
- EML4 | c.87A>G p.S29= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100580869; called by muse, mutect2, varscan2
- ENPP3 | c.2241T>C p.S747= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100717230; called by muse, mutect2, varscan2
- EPB41L4B | c.1776G>A p.E592= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV101000909; called by muse, mutect2, varscan2
- FAM184A | c.1482T>A p.I494= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100137749; called by muse, mutect2, varscan2
- FARP1 | c.2172G>C p.V724= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100130586; called by muse, mutect2, varscan2
- FBXO40 | c.1824C>A p.A608= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100573149; called by muse, mutect2, varscan2
- FCRL3 | c.1734G>A p.T578= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs767531795; called by muse, mutect2, varscan2
- FGF12 | c.120G>A p.L40= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as COSV53151596, COSV53160969, COSV99280973; called by muse, mutect2, varscan2
- FMN2 | c.1980C>G p.V660= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1253616614, COSV100144886, COSV60443198; called by muse, mutect2, varscan2
- GPR17 | c.1029A>G p.K343= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV99760568; called by muse, mutect2, varscan2
- GRIN2B | c.1578T>C p.S526= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV101663021; called by muse, mutect2, varscan2
- GUCY1A1 | c.813C>A p.P271= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99637671; called by muse, mutect2, varscan2
- HDGFL1 | c.234G>T p.G78= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100014572; called by muse, varscan2
- HSF4 | c.726G>A p.Q242= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99263506; called by muse, mutect2, varscan2
- IFI44L | c.345T>C p.R115= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs756432982, COSV100654978; called by muse, mutect2, varscan2
- IPO4 | c.2037C>T p.A679= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1362384604, COSV100269003; called by muse, mutect2, varscan2
- KIAA1755 | c.1371T>C p.P457= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99641978; called by muse, mutect2, varscan2
- KRT6B | c.1134G>A p.K378= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs752907331, COSV99360684; called by muse, mutect2, varscan2
- LAMA2 | c.4827G>T p.L1609= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV101370432; called by muse, mutect2, varscan2
- MAB21L2 | c.795C>A p.P265= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100462143; called by muse, mutect2, varscan2
- MBOAT7 | c.87G>A p.L29= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99824799; called by muse, mutect2
- MOGAT1 | c.414A>T p.S138= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV71480150; called by muse, mutect2, varscan2
- MRPL21 | c.165C>A p.S55= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs749239284, COSV100751901; called by muse, mutect2, varscan2
- MYBPH | c.687C>G p.S229= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99704516; called by muse, mutect2, varscan2
- NAV3 | c.4362C>T p.D1454= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1480510108, COSV99890504; called by muse, mutect2, varscan2
- NCR2 | c.93G>A p.V31= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100897221; called by muse, mutect2, varscan2
- NEK10 | c.3075G>T p.V1025= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99835147; called by muse, mutect2, varscan2
- NMD3 | c.1050A>G p.T350= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100664686; called by muse, mutect2, varscan2
- NPY1R | c.153C>A p.I51= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV56713310, COSV99648723; called by muse, mutect2, varscan2
- NUDT6 | c.762G>T p.L254= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99144634; called by muse, mutect2, varscan2
- NUF2 | c.1023C>T p.F341= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV54845206; called by muse, mutect2, varscan2
- OPRK1 | c.573C>A p.I191= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV55571517, COSV99654040; called by muse, mutect2, varscan2
- OR12D2 | c.15C>G p.T5= | Silent (SNP) | VAF 43/208 reads (21%) | catalogued as COSV101011270; called by muse, mutect2, varscan2
- PCDH10 | c.1011C>A p.A337= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs747562065, COSV99993493; called by muse, mutect2, varscan2
- PDGFRA | c.3249G>T p.L1083= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV99956515; called by muse, mutect2, varscan2
- PHLDB2 | c.1602C>T p.T534= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as COSV101208509; called by muse, mutect2, varscan2
- PKMYT1 | c.1242T>A p.P414= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- PKN2 | c.1647A>T p.V549= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100281583; called by muse, mutect2, varscan2
- PLCL2 | c.493C>T p.L165= (on ENST00000615277 / NM_001144382.2; = p.L39= on NM_015184.5) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV101196726; called by muse, mutect2, varscan2
- PNLIPRP1 | c.522C>G p.A174= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as COSV100724374; called by muse, mutect2, varscan2
- PRAMEF15 | c.1152C>T p.T384= | Silent (SNP) | VAF 61/312 reads (20%) | catalogued as rs1212946307; called by muse, mutect2, varscan2
- PTPRM | c.1083T>A p.G361= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100157048; called by muse, mutect2, varscan2
- QARS1 | c.6G>C p.A2= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100070001; called by muse, mutect2, varscan2
- SETD1A | c.2319C>T p.P773= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99352922; called by muse, mutect2, varscan2
- SLITRK3 | c.504A>T p.A168= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99579178; called by muse, mutect2, varscan2
- SPHKAP | c.4794T>A p.P1598= (on ENST00000392056 / NM_001142644.2; = p.P1569= on NM_030623.3) | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100764105; called by muse, mutect2, varscan2
- STAC | c.780A>T p.P260= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99829949; called by muse, mutect2
- SYT13 | c.267G>C p.V89= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV99194706; called by muse, mutect2, varscan2
- THSD7B | c.2847A>C p.G949= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV99750030; called by muse, mutect2, varscan2
- TMEM200C | c.270G>C p.P90= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV101274832, COSV67309308; called by muse, mutect2, varscan2
- UBE2S | c.196C>T p.L66= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99198774; called by muse, mutect2
- UBE3D | c.234A>C p.G78= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV99388443; called by muse, mutect2, varscan2
- UGT2B15 | c.1242C>T p.L414= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as COSV100592309; called by muse, mutect2, varscan2
- UGT3A1 | c.813G>A p.L271= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57098351; called by muse, mutect2, varscan2
- UTP23 | c.312G>T p.L104= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV99411871; called by muse, mutect2, varscan2
- WFS1 | c.1206G>C p.L402= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV99901242; called by muse, mutect2, varscan2
- ZFHX4 | c.4941G>A p.Q1647= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99262428; called by muse, mutect2, varscan2
- ZNF329 | c.933G>C p.G311= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV100798731; called by muse, mutect2, varscan2
- ZNF440 | c.1677A>G p.E559= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs1400548181, COSV100407522; called by muse, mutect2, varscan2
- ZNF582 | c.132A>G p.S44= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV100018688; called by muse, mutect2, varscan2
- ZNF804A | c.471G>T p.V157= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100167713; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-808C>G | Intron (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100760368; called by muse, mutect2, varscan2
- BTN2A3P | n.400G>A | RNA (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- C8orf31 | n.716C>G | RNA (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- EYA4 | c.1757-99C>G | Intron (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100765718, COSV62059729; called by muse, mutect2, varscan2
- GBA3 | c.59-8237C>T | Intron (SNP) | VAF 45/189 reads (24%) | catalogued as rs11544900; called by muse, mutect2, varscan2
- PDLIM3 | c.93+10271C>T | Intron (SNP) | VAF 38/114 reads (33%) | catalogued as rs769091239, COSV99507563; called by muse, mutect2, varscan2
- SNORD115-14 | n.72G>C | RNA (SNP) | VAF 118/301 reads (39%) | catalogued as rs574481458; called by muse, mutect2, varscan2
